Gene-level copy-number profile of specimen HCM-SANG-0309-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0309-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0309-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9e50870e-ac26-49cd-a077-89f263075de5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0309-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/b5c69baf-e31f-4404-b1d3-16e581fc1747

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 418; copy number 2: 21,453; copy number 3: 18,327; copy number 4: 12,670; copy number 5: 3,410; copy number 6: 1,930; copy number 7: 74; copy number 8: 123; copy number 9: 144; copy number 10: 31; copy number 11: 46; copy number 12: 35; copy number 13: 22; copy number 14: 21; copy number 15: 7; copy number 17: 68; copy number 18: 46; copy number 20: 2; copy number 28: 20; copy number 34: 1; copy number 35: 15.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,409,009–19,967,994, 10 genes: ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3.
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,480,839–23,438,700, 26 genes (within-gene range 0–2): IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,995 genes in 87 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–9,440,564, 312 genes, copy number 5–7 (broad region; genes not listed).
- chr1:18,904,280–20,091,911, 29 genes, copy number 5–8 (within-gene range 3–8): IFFO2, AL137127.1, UBR4, EMC1-AS1, EMC1, MRTO4, AKR7L, AKR7A3, AL035413.1, AKR7A2, RNU6-1099P, SLC66A1, CAPZB, RN7SL277P, MICOS10, RNU4-28P, AL031727.2, NBL1, MICOS10-NBL1, AL031727.1, HTR6, TMCO4, RNF186, AL391883.1, OTUD3, PLA2G2E, RN7SL304P, PLA2G2A, PLA2G5.
- chr1:20,552,573–21,176,888, 16 genes, copy number 5 (within-gene range 4–5): FAM43B, CDA, PINK1, MIR6084, PINK1-AS, DDOST, KIF17, AL663074.2, SH2D5, AL663074.1, HP1BP3, EIF4G3, RNU7-200P, MIR1256, RPS15AP6, AL627311.1.
- chr1:21,217,247–22,157,401, 35 genes, copy number 5–6: ECE1, AL031005.1, ECE1-AS1, PPP1R11P1, AL592309.1, AL592309.2, NBPF2P, HS6ST1P1, CROCCP5, NBPF3, PFN1P10, ALPL, LINC02596, RAP1GAP, USP48, AL590103.1, LDLRAD2, HSPG2, AL590556.1, CELA3B, AL590556.3, RN7SL386P, RNU6-1022P, CELA3A, RN7SL186P, RNU6-776P, LINC01635, LINC00339, CDC42, CDC42-AS1, AL031281.1, CDC42-IT1, MPHOSPH6P1, WNT4, AL445253.1.
- chr1:143,419,625–150,287,093, 245 genes, copy number 5 (broad region; genes not listed).
- chr1:150,600,851–157,820,120, 386 genes, copy number 5 (broad region; genes not listed).
- chr1:158,289,923–175,204,849, 451 genes, copy number 5–6 (broad region; genes not listed).
- chr1:175,315,194–176,845,601, 18 genes, copy number 5 (within-gene range 4–5): TNR, TNR-IT1, LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7, PAPPA2, PTP4A1P7, AL031290.1.
- chr1:177,351,562–184,629,019, 140 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:38,814–58,296,817, 910 genes, copy number 5–7 (broad region; genes not listed).
- chr2:86,815,339–89,887,247, 107 genes, copy number 5–12 (broad region; genes not listed).
- chr2:96,824,526–100,722,882, 88 genes, copy number 7–18 (within-gene range 4–18) (broad region; genes not listed).
- chr2:104,583,138–105,438,513, 26 genes, copy number 5: AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1.
- chr6:10,980,759–11,709,960, 17 genes, copy number 7: ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1.
- chr9:26,746,953–27,573,866, 22 genes, copy number 6: AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72.
- chr9:33,401,478–33,662,663, 19 genes, copy number 5–6 (within-gene range 4–6): AL356218.2, AQP3, AL356218.1, NOL6, MIR6851, SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7, CYP4F26P, PRSS3P4, TRBV20OR9-2, ANXA2P2, TRBV21OR9-2, TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2.
- chr9:34,889,066–37,592,604, 106 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:38,147,428–40,883,763, 72 genes, copy number 5–6 (broad region; genes not listed).
- chr9:42,183,659–42,714,539, 17 genes, copy number 5: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr9:61,190,003–72,365,235, 216 genes, copy number 5–8 (broad region; genes not listed).
- chr10:21,174,014–38,783,108, 315 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:68,612,899–72,843,674, 147 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:73,510,658–79,612,300, 171 genes, copy number 6–9 (broad region; genes not listed).
- chr11:84,545,131–85,935,663, 20 genes, copy number 6: HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1.
- chr11:86,374,736–87,021,909, 16 genes, copy number 5: CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT.
- chr12:12,568,201–13,142,521, 28 genes, copy number 5: AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47, AC007215.1, AC007688.2, RPL13AP20, GPRC5A, MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1, HEBP1, HTR7P1, AC023790.2, AC023790.1, FAM234B, GSG1.
- chr12:55,729,104–56,636,816, 69 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:64,264,762–66,170,072, 54 genes, copy number 6–7 (within-gene range 4–7): C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:67,929,235–68,793,964, 26 genes, copy number 6: LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3.
- chr15:41,609,457–42,412,949, 30 genes, copy number 5 (within-gene range 3–5): AC016134.1, MGA, MIR626, AC073657.2, AC073657.1, MAPKBP1, AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1, EHD4, AC039056.2, EHD4-AS1, PLA2G4E-AS1, PLA2G4E, AC039056.1, PLA2G4D, PLA2G4F, VPS39, MIR627, AC036103.1, TMEM87A, GANC, BNIP3P5, AC012651.1, CAPN3.
- chr15:59,574,103–80,597,933, 557 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:35,085,896–35,912,516, 73 genes, copy number 5 (broad region; genes not listed).
- chr16:71,358,713–71,809,201, 26 genes, copy number 5: CALB2, LINC02136, AC010547.6, TLE7, AC010547.5, ZNF23, AC010547.4, AC010547.1, ZNF19, AC010547.3, CHST4, AC010547.2, RNU6-1061P, TAT-AS1, TAT, AC009097.2, MARVELD3, PHLPP2, AC009097.1, RNU6-208P, SNORA70D, AC009097.4, AC009097.3, AP1G1, SNORD71, AC010653.3.
- chr16:75,497,948–75,861,157, 20 genes, copy number 5: AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231, AC025287.1, AC025287.2, GABARAPL2, AC025287.3, ADAT1, KARS1, AC025287.5, TERF2IP, AC025287.4, DUXB, RN7SL520P, ATP5PBP7, CPHXL, AC105430.1, RNA5SP430.
- chr17:39,238,466–42,194,532, 179 genes, copy number 10–35 (broad region; genes not listed).
- chr18:45,034–15,330,282, 367 genes, copy number 6 (broad region; genes not listed).
- chr18:23,134,564–27,595,164, 82 genes, copy number 5–18 (broad region; genes not listed).
- chr19:28,065,267–30,016,612, 40 genes, copy number 5–18: AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr19:35,042,902–39,738,029, 266 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:16,177,933–18,220,512, 41 genes, copy number 5: AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2.

Autosomal genes at a single copy (total copy number 1): 418. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
